Somatic mutation profile of tumor specimen TCGA-G3-A7M9-01A (aliquot TCGA-G3-A7M9-01A-23D-A34Z-10) from TCGA case TCGA-G3-A7M9, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 70.1 years (25,588 days).
Specimen TCGA-G3-A7M9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b40957ea-2fb4-4362-8d1e-44242cdddb53.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-A7M9-10A (Blood Derived Normal), aliquot TCGA-G3-A7M9-10A-01D-A34Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31e68bf7-79e2-4bdb-82ac-b63cd2307ab7

The open-access MAF lists 127 somatic variants for this specimen: 97 protein-altering or splice-affecting, 29 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 29, Frame Shift Del 7, Nonsense Mutation 2, Splice Site 2, In Frame Del 1, Nonstop Mutation 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.11800G>T p.E3934* | Nonsense Mutation (SNP) | VAF 20/54 reads (37%) | catalogued as COSV71293421, COSV71294286; called by muse, mutect2, varscan2
- AC109583.1 | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV58406461; called by muse, mutect2, varscan2
- ACTR6 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.171); catalogued as COSV51843090; called by muse, mutect2, varscan2
- ADGRV1 | c.3568C>T p.H1190Y | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.125); catalogued as rs780302289, COSV67993910; called by muse, mutect2, varscan2
- AKAP4 | c.1457C>A p.P486Q | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV62075375; called by muse, varscan2
- AMOTL2 | c.2338T>G p.*780Gext*43 (on ENST00000422605; = p.*781Gext*43 on NM_016201.4) | Nonstop Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV51440658; called by muse, varscan2
- ARNT2 | c.265A>G p.M89V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV57589873; called by muse, mutect2, varscan2
- ASCC3 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV61232768; called by muse, mutect2, varscan2
- ATP2C2 | c.496G>T p.V166F | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs756655642, COSV52300694; called by muse, mutect2, varscan2
- CBX4 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs138355116, COSV53965871; called by muse, mutect2, varscan2
- CFI | c.483-2A>T p.X161_splice | Splice Site (SNP) | VAF 7/14 reads (50%) | catalogued as COSV67099727; called by muse, mutect2, varscan2
- CHDH | c.1681A>G p.I561V | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV55462645; called by muse, mutect2, varscan2
- COL5A1 | c.1424G>A p.G475D | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as CM128974, COSV65673831; called by muse, mutect2, varscan2
- CPNE9 | c.989A>G p.Y330C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs560497816, COSV104381771, COSV56069666; called by muse, mutect2, varscan2
- DDR1 | c.2476G>T p.V826L (on ENST00000324771; = p.V789L on NM_001954.4) | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs771341445, COSV61324827; called by muse, mutect2, varscan2
- DIP2C | c.3694T>C p.S1232P | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV55176212; called by muse, mutect2, varscan2
- DNAJB5 | c.101A>C p.D34A | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56627297; called by muse, mutect2, varscan2
- DSPP | c.1448A>G p.N483S | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.047); catalogued as COSV56815529; called by muse, mutect2, varscan2
- ENDOG | c.866T>G p.L289R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as COSV63510004; called by mutect2, varscan2
- EPHA7 | c.473G>A p.G158D | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.42); PolyPhen probably damaging (1); catalogued as rs1286516366, COSV65170326; called by muse, mutect2, varscan2
- ERN2 | c.101C>A p.T34N | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV99891649; called by muse, mutect2
- FAHD2B | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767328246, COSV55632137; called by muse, mutect2, varscan2
- FAM13C | c.920T>C p.F307S | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53254879; called by muse, mutect2, varscan2
- FCGR1A | c.293T>A p.L98Q | Missense Mutation (SNP) | VAF 82/259 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64986016; called by muse, mutect2, varscan2
- FIGN | c.98G>C p.R33P | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.989); catalogued as COSV60771209, COSV60772562; called by muse, mutect2, varscan2
- FN1 | c.3953C>A p.P1318H | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1362134539, COSV60562363; called by muse, mutect2, varscan2
- FRAS1 | c.3097G>T p.V1033F | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV53641992; called by muse, mutect2
- FRMD4A | c.2181C>A p.S727R | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.057); catalogued as COSV62268771; called by muse, mutect2, varscan2
- GPC5 | c.1415G>T p.R472I | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.405); catalogued as COSV65625223; called by muse, varscan2
- GREB1 | c.511T>C p.F171L | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV52195090; called by muse, mutect2, varscan2
- GUF1 | c.1606T>C p.Y536H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55784617; called by muse, mutect2, varscan2
- HELT | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV58820462; called by muse, mutect2, varscan2
- HEPACAM2 | c.915A>T p.K305N (on ENST00000394468 / NM_001039372.4; = p.K293N on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.196); catalogued as COSV59057966; called by muse, mutect2, varscan2
- IMPG1 | c.858A>T p.L286F | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV64061099; called by muse, mutect2, varscan2
- INPPL1 | c.1780G>T p.D594Y | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53358893; called by muse, mutect2, varscan2
- INSL4 | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV53329834, COSV53329980; called by muse, mutect2, varscan2
- ITGB4 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.605); catalogued as rs146966502, COSV52331798; called by muse, mutect2, varscan2
- ITPR3 | c.2780T>C p.M927T | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as COSV65414313; called by muse, mutect2, varscan2
- KHDC3L | c.237G>T p.L79F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV64869699; called by muse, mutect2, varscan2
- KHDC3L | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64869705; called by muse, mutect2, varscan2
- KRTAP10-2 | c.526T>A p.S176T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV59977747; called by muse, mutect2, varscan2
- LRMDA | c.74G>A p.R25K | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV65282388; called by muse, mutect2, varscan2
- LVRN | c.1074G>C p.L358F | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV63498244; called by muse, mutect2, varscan2
- MAP3K7 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65235146; called by muse, mutect2, varscan2
- MMUT | c.6A>T p.L2F | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as COSV51281087; called by muse, mutect2, varscan2
- NBEAL2 | c.3296A>G p.E1099G | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.236); catalogued as COSV52762412; called by muse, mutect2, varscan2
- NELFB | c.1040+1G>T p.X347_splice | Splice Site (SNP) | VAF 18/28 reads (64%) | catalogued as COSV58026278; called by muse, mutect2, varscan2
- NFXL1 | c.2587A>T p.R863* | Nonsense Mutation (SNP) | VAF 34/108 reads (31%) | catalogued as COSV67432580; called by muse, mutect2, varscan2
- NGFR | c.736G>C p.G246R | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV50804002; called by muse, mutect2, varscan2
- NPY5R | c.878C>T p.T293I | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.05); PolyPhen benign (0.425); catalogued as rs146231711; called by muse, mutect2, varscan2
- NTRK1 | c.1153T>C p.F385L | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as COSV62328269; called by muse, varscan2
- OBSCN | c.12740C>T p.A4247V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as rs756076165, COSV52778949, COSV52821035; called by muse, varscan2
- OR10T2 | c.424G>T p.G142W | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100554973, COSV57783148, COSV57783499; called by muse, varscan2
- OR4C46 | c.374G>T p.C125F | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV60221017; called by muse, mutect2, varscan2
- PAK3 | c.865A>G p.I289V (on ENST00000262836 / NM_001324328.2; = p.I274V on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/89 reads (83%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as rs1395819172, COSV53279710; called by muse, mutect2, varscan2
- PCDH15 | c.5126C>A p.A1709D | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious, low confidence (0.01); catalogued as COSV64729069; called by muse, mutect2, varscan2
- PCDHA7 | c.2021A>T p.Q674L | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); catalogued as COSV65340057; called by muse, mutect2, varscan2
- PCLO | c.13522G>A p.V4508I | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV61661211; called by muse, mutect2, varscan2
- PDZD7 | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64647381; called by muse, mutect2, varscan2
- PLD4 | c.1243G>T p.V415L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as rs1456619635, COSV66915645; called by muse, mutect2, varscan2
- PPFIBP1 | c.204A>T p.E68D | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV57297818; called by muse, mutect2, varscan2
- PTX3 | c.561G>A p.M187I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55822154; called by muse, mutect2, varscan2
- RNF149 | c.553A>G p.I185V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.232); catalogued as rs1201528746, COSV54865280; called by muse, mutect2, varscan2
- RPL18 | c.79C>A p.L27M | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV50032253; called by muse, mutect2, varscan2
- RYR1 | c.3763G>A p.E1255K | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.164); catalogued as rs1186295753, COSV62099667, COSV62108758; called by muse, mutect2, varscan2
- RYR2 | c.3022G>T p.A1008S | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); catalogued as COSV63709775; called by muse, mutect2, varscan2
- RYR3 | c.2113G>T p.V705F | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66806180; called by muse, mutect2, varscan2
- SEPTIN9 | c.50G>C p.R17P | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.776); catalogued as COSV70726204, COSV70728549; called by muse, mutect2, varscan2
- SH2B3 | c.1442T>C p.L481P | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV57986232; called by muse, mutect2, varscan2
- SI | c.3320C>A p.P1107Q | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52268611; called by muse, mutect2, varscan2
- SLCO6A1 | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs868479532, COSV65814138; called by muse, mutect2, varscan2
- SPRR4 | c.152A>C p.K51T | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.463); catalogued as COSV100044540, COSV60143211; called by muse, mutect2, varscan2
- STAB1 | c.3199G>T p.A1067S | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.077); catalogued as COSV58742080; called by mutect2, varscan2
- TAAR1 | c.439A>G p.S147G | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.289); catalogued as rs982989326, COSV51589311; called by muse, mutect2, varscan2
- TDRD6 | c.4376A>T p.E1459V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV60178183; called by muse, mutect2, varscan2
- TFAP2D | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50450469; called by muse, mutect2, varscan2
- THBS2 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as rs577676627, COSV64681307; called by muse, mutect2, varscan2
- TLE4 | c.424C>A p.H142N | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV54640223; called by muse, mutect2, varscan2
- TMEM132B | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs781583695, COSV54767213; called by muse, mutect2, varscan2
- TNKS | c.1043A>T p.E348V | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.809); catalogued as COSV60065480; called by muse, mutect2, varscan2
- TP63 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs751300168, COSV53195986; called by muse, mutect2, varscan2
- TRPS1 | c.2802C>A p.N934K (on ENST00000220888 / NM_001330599.2; = p.N947K on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55258780; called by muse, mutect2, varscan2
- TSTD2 | c.1264T>C p.C422R | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1309622476, COSV52251978; called by muse, mutect2, varscan2
- TUBGCP6 | c.395A>G p.Y132C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1334859443, COSV50576955; called by muse, mutect2, varscan2
- VAV1 | c.1713C>A p.F571L | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV58388890, COSV58390762; called by muse, mutect2, varscan2
- WFS1 | c.2128A>C p.T710P | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV56991331; called by muse, mutect2, varscan2
- XPOT | c.715C>A p.L239I | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.906); catalogued as COSV60347737; called by muse, mutect2, varscan2
- ZFHX4 | c.8988G>A p.M2996I | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.956); catalogued as rs779366252, COSV50666238; called by muse, mutect2, varscan2
- CSF3R | c.1353_1367del p.P452_P456del | In Frame Del (DEL) | VAF 6/43 reads (14%) | called by mutect2, pindel
- HSP90AA1 | c.1867_1871del p.S623Nfs*15 | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | called by mutect2, varscan2
- MYO3A | c.3525del p.T1176Pfs*17 | Frame Shift Del (DEL) | VAF 23/62 reads (37%) | called by mutect2, pindel, varscan2
- SLCO1C1 | c.1573_1576del p.G525Lfs*12 | Frame Shift Del (DEL) | VAF 26/74 reads (35%) | called by mutect2, pindel, varscan2
- SPHK1 | c.25_41del p.G9Lfs*30 (on ENST00000392496 / NM_001355139.2; = p.G23Lfs*30 on NM_021972.4) | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | called by mutect2, pindel, varscan2
- SYNE2 | c.13591_13600del p.K4531Lfs*5 | Frame Shift Del (DEL) | VAF 24/62 reads (39%) | called by mutect2, pindel, varscan2
- TOB1 | c.717_718dup p.P240Rfs*84 | Frame Shift Ins (INS) | VAF 7/22 reads (32%) | called by mutect2, pindel, varscan2
- TP53 | c.579_585del p.L194Efs*51 | Frame Shift Del (DEL) | VAF 12/25 reads (48%) | called by mutect2, pindel, varscan2
- TRIP10 | c.1331_1340del p.E444Afs*5 (on ENST00000313244 / NM_001288962.2; = p.E388Afs*5 on NM_004240.4) | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | called by mutect2, pindel, varscan2
- ABCA5 | c.1560G>A p.K520= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV67018792; called by muse, mutect2, varscan2
- ARHGAP15 | c.960C>A p.G320= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as COSV54517494; called by muse, mutect2, varscan2
- CDHR5 | c.1485C>T p.G495= (on ENST00000358353 / NM_001171968.2; = p.G501= on NM_021924.5) | Silent (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- CDRT1 | c.33C>T p.A11= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as COSV55413288; called by muse, mutect2, varscan2
- CGN | c.2299C>T p.L767= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV54973099; called by muse, mutect2, varscan2
- DYNC1H1 | c.900T>G p.T300= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV64141643; called by muse, mutect2, varscan2
- ECD | c.837A>C p.P279= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV65901103; called by muse, mutect2, varscan2
- GATA4 | c.1197C>T p.V399= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs778818575, COSV58735470; called by muse, mutect2, varscan2
- GCLM | c.753G>A p.S251= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs567112849, COSV64686989; called by muse, mutect2, varscan2
- IPO8 | c.1443T>G p.L481= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV56245097; called by muse, varscan2
- ITPKB | c.1761A>C p.G587= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV55268253; called by muse, mutect2, varscan2
- KIF21B | c.4375C>T p.L1459= (on ENST00000422435 / NM_001252100.2; = p.L1446= on NM_017596.4) | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV59764853; called by muse, mutect2, varscan2
- LENG8 | c.969G>A p.A323= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs985703953, COSV58727708; called by muse, varscan2
- MAP2K1 | c.396G>A p.A132= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as rs139364105, COSV61073184; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYH9 | c.4041G>A p.E1347= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV53392305; called by muse, mutect2, varscan2
- NUP205 | c.3372A>G p.L1124= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV53665187; called by muse, mutect2, varscan2
- NUP210L | c.2031G>C p.G677= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV55156223; called by muse, mutect2, varscan2
- PAX2 | c.1086G>A p.V362= (on ENST00000428433 / NM_003987.5; = p.V339= on NM_000278.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV62292779; called by muse, mutect2, varscan2
- SLC6A15 | c.705C>A p.A235= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV57028847; called by muse, mutect2, varscan2
- SORCS1 | c.1344C>T p.F448= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs1564872118, COSV53899825; called by muse, mutect2, varscan2
- STEAP3 | c.753C>A p.P251= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV61530807; called by muse, mutect2, varscan2
- TEK | c.2406C>A p.A802= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV66232951; called by muse, mutect2, varscan2
- TMEM214 | c.1032G>A p.Q344= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as COSV53193869; called by muse, mutect2, varscan2
- TRDMT1 | c.450T>C p.S150= | Silent (SNP) | VAF 33/112 reads (29%) | catalogued as COSV58320731; called by muse, mutect2, varscan2
- TRMO | c.1134G>T p.V378= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV64293017, COSV64293597; called by muse, mutect2, varscan2
- TTLL12 | c.828C>T p.A276= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs745511557, COSV53354959; called by muse, mutect2, varscan2
- TUT7 | c.495G>T p.T165= | Silent (SNP) | VAF 37/132 reads (28%) | catalogued as COSV52895598; called by muse, mutect2, varscan2
- ZNF28 | c.1215T>C p.H405= | Silent (SNP) | VAF 29/45 reads (64%) | catalogued as rs1297636053, COSV60425099; called by muse, mutect2, varscan2
- ZNF582 | c.615G>A p.G205= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV56733531; called by muse, mutect2, varscan2
- MGAT4B | c.1511-16C>T | Intron (SNP) | VAF 9/17 reads (53%) | catalogued as rs1479021409, COSV52979368; called by muse, mutect2, varscan2
